Somatic mutation profile of cancer-model specimen HCM-BROD-0650-C56-85N (3D Organoid, passage 8; aliquot HCM-BROD-0650-C56-85N-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0650-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,542 days).
Specimen HCM-BROD-0650-C56-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5e2cc59-c454-4f89-b6a3-3a6ba2e8d4cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0650-C56-12A (Saliva), aliquot HCM-BROD-0650-C56-12A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b131809-ffe9-45af-a5a6-ec2786ae79d3

The open-access MAF lists 179 somatic variants for this specimen: 136 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 37, Intron 5, Nonsense Mutation 5, In Frame Del 3, Frame Shift Ins 2, Splice Site 1, 3'UTR 1, Frame Shift Del 1, Splice Region 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4282G>T p.V1428F (on ENST00000303395 / NM_001202435.3; = p.V1417F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878854263; ClinVar: pathogenic; called by muse, varscan2
- ANKS1B | c.2017A>T p.I673F | Missense Mutation (SNP) | VAF 50/606 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV61349555, COSV61368911; called by muse, mutect2
- APOB | c.8245A>G p.T2749A | Missense Mutation (SNP) | VAF 157/531 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1429563329, COSV99266420; called by muse, mutect2, varscan2
- ARHGAP42 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1565284108; called by muse, mutect2
- ATP10A | c.3545G>A p.S1182N | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs564882602; called by muse, mutect2, varscan2
- ATP1A3 | c.1162C>T p.R388C (on ENST00000545399 / NM_001256214.2; = p.R375C on NM_152296.5) | Missense Mutation (SNP) | VAF 314/487 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1057524683, COSV57488873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG4 | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV54860708; called by muse, mutect2
- BPTF | c.418_447del p.M140_D149del | In Frame Del (DEL) | VAF 164/357 reads (46%) | catalogued as rs759306365; called by pindel*, varscan2
- CASP8 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 81/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747668924; called by muse, mutect2, varscan2
- CCER1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 223/833 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1211501476; called by muse, mutect2, varscan2
- CFAP46 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 200/505 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs777460078; called by muse, mutect2, varscan2
- CFAP47 | c.9518G>A p.G3173E | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1395924702; called by muse, mutect2, varscan2
- CYC1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 151/613 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1371182397, COSV59644447; called by muse, mutect2, varscan2
- CYP11B2 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 418/628 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780112807, COSV59995495; called by muse, mutect2, varscan2
- DDI1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 248/735 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs779548652, COSV56371148; called by muse, mutect2, varscan2
- DNAAF5 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 147/314 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs779352236, COSV52414902; called by muse, mutect2, varscan2
- ELMO1 | c.1822C>T p.L608= | Splice Region (SNP) | VAF 18/412 reads (4%) | catalogued as rs1198368379; called by muse, mutect2
- ELOVL7 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 138/280 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781379671; called by muse, mutect2, varscan2
- EMILIN1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 197/576 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1278526194, COSV66694838; called by muse, mutect2, varscan2
- EPN2 | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV59059771; called by muse, mutect2, varscan2
- FBN1 | c.4894C>T p.R1632C | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs544990350; called by muse, mutect2, varscan2
- FMOD | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 151/600 reads (25%) | catalogued as COSV61610479; called by muse, mutect2, varscan2
- HGD | c.1252T>G p.C418G | Missense Mutation (SNP) | VAF 159/632 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52198574; called by muse, mutect2, varscan2
- IFIH1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 35/509 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs372313271; called by muse, mutect2
- IL13RA2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781815956; called by muse, mutect2, varscan2
- ITIH5 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 34/600 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762603415, COSV56909593; called by muse, mutect2
- KCNJ15 | c.693C>A p.N231K | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV60811219; called by muse, mutect2, varscan2
- LARP1B | c.1174G>C p.V392L | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1445124526; called by muse, mutect2, varscan2
- MAGEB2 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 155/159 reads (97%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs1391671203, COSV100975752; called by muse, mutect2, varscan2
- MARF1 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 81/535 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.207); catalogued as COSV60024872; called by muse, mutect2, varscan2
- MUC5B | c.11146C>T p.P3716S | Missense Mutation (SNP) | VAF 60/740 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs565982586; called by muse, mutect2
- MYB | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100214866; called by muse, mutect2, varscan2
- NF2 | c.576C>A p.Y192* | Nonsense Mutation (SNP) | VAF 128/134 reads (96%) | catalogued as CM994608, COSV100097796, COSV58520186, COSV58532890; called by mutect2, varscan2
- NRXN3 | c.2366A>G p.K789R (on ENST00000335750 / NM_001330195.2; = p.K416R on NM_004796.6) | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as COSV100200419; called by muse, mutect2
- PGBD5 | c.1285G>C p.V429L (on ENST00000525115; = p.V498L on NM_001258311.2) | Missense Mutation (SNP) | VAF 171/548 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.091); catalogued as rs148414368, COSV58412934; called by muse, mutect2, varscan2
- PNLIPRP1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 157/602 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs116575931, COSV100724521, COSV62613062; called by muse, mutect2, varscan2
- RAD51AP2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.181); catalogued as rs1341118226; called by muse, mutect2
- RPTN | c.982A>C p.S328R | Missense Mutation (SNP) | VAF 60/716 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV60166831; called by muse, mutect2
- SLC35G3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 36/720 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs376097709; called by muse, mutect2
- SLFN14 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1463851112; called by muse, mutect2, varscan2
- SLITRK3 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 204/741 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1490316717, COSV53852040; called by muse, mutect2, varscan2
- SMO | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 42/1281 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV50825620; called by muse, mutect2
- TNFAIP3 | c.2186G>C p.S729T | Missense Mutation (SNP) | VAF 18/567 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0.185); catalogued as COSV52797207; called by muse, mutect2
- TRAPPC5 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 328/837 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as rs1202159236; called by muse, mutect2, varscan2
- WDR31 | c.1028G>T p.S343I (on ENST00000374193 / NM_001006615.3; = p.S342I on NM_145241.5) | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100516734; called by muse, mutect2
- ZC3H13 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54447724; called by muse, mutect2
- AAK1 | c.7_9del p.K3del | In Frame Del (DEL) | VAF 36/320 reads (11%) | called by pindel, varscan2
- ACTR5 | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 30/686 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ADAM12 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADPRHL1 | c.2305C>A p.P769T | Missense Mutation (SNP) | VAF 47/1133 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2
- AFP | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2
- AGO4 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ANK3 | c.6646G>C p.V2216L | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2
- ANKRD18B | c.1256A>C p.H419P | Missense Mutation (SNP) | VAF 163/347 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- APOA4 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 52/629 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.359); called by muse, mutect2
- APOBR | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.354); called by mutect2, varscan2
- ATP7A | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BCHE | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- BCL7C | c.554G>T p.R185I | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- BIRC6 | c.8194A>G p.M2732V | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- BMP8B | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 14/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1QTNF9 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 209/413 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C1QTNF9B | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2CD3 | c.6801C>G p.S2267R | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CACNA1C | c.5718G>C p.E1906D (on ENST00000399634 / NM_001167625.1; = p.E1835D on NM_000719.7) | Missense Mutation (SNP) | VAF 121/533 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPER2 | c.996dup p.R333Sfs*11 | Frame Shift Ins (INS) | VAF 36/138 reads (26%) | called by mutect2, pindel, varscan2
- CCPG1 | c.1848T>A p.H616Q | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH20 | c.2180T>C p.L727P | Missense Mutation (SNP) | VAF 22/566 reads (4%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.961); called by muse, mutect2
- CEP152 | c.740C>G p.A247G | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN6 | c.2990dup p.L997Ffs*12 | Frame Shift Ins (INS) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- COPS3 | c.687A>T p.L229F | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CPAMD8 | c.392G>A p.G131E (on ENST00000651564; = p.G84E on NM_015692.5) | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CR1 | c.3844G>T p.V1282L | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- CREB3L2 | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CSDE1 | c.1753+1del p.X585_splice (on ENST00000358528 / NM_001007553.3; = p.X554_splice on NM_007158.6) | Splice Site (DEL) | VAF 89/253 reads (35%) | called by mutect2, pindel, varscan2
- CTBS | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CTNNB1 | c.700T>G p.S234A | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.111); called by muse, mutect2
- CUBN | c.6148C>G p.L2050V | Missense Mutation (SNP) | VAF 36/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- DOP1B | c.4547A>G p.H1516R | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DPYSL4 | c.1204G>C p.A402P | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- DROSHA | c.2103G>C p.Q701H | Missense Mutation (SNP) | VAF 102/713 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DYNC1I2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 23/487 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ECI2 | c.590_607del p.S197_L202del (on ENST00000380118 / NM_206836.3; = p.S167_L172del on NM_006117.2) | In Frame Del (DEL) | VAF 51/266 reads (19%) | called by mutect2, pindel, varscan2
- EDN1 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2
- EDNRB | c.461G>A p.R154Q (on ENST00000377211 / NM_001201397.1; = p.R64Q on NM_000115.5) | Missense Mutation (SNP) | VAF 48/720 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- EIF4G1 | c.4569G>C p.Q1523H (on ENST00000346169 / NM_198241.3; = p.Q1328H on NM_004953.5) | Missense Mutation (SNP) | VAF 39/627 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- EIF4G1 | c.4570G>T p.A1524S (on ENST00000346169 / NM_198241.3; = p.A1329S on NM_004953.5) | Missense Mutation (SNP) | VAF 39/627 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- EPHA10 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 40/561 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- F7 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM20A | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 38/638 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM71B | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 44/800 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.444); called by muse, mutect2
- FARP2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBN2 | c.3767A>T p.Q1256L | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNF1A | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 507/789 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- JADE1 | c.2438A>G p.E813G | Missense Mutation (SNP) | VAF 171/348 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MAB21L2 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 49/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAMDC4 | c.2742_2762dup p.Q914_A920dup (on ENST00000445819; = p.Q835_A841dup on NM_206920.3) | In Frame Ins (INS) | VAF 112/418 reads (27%) | called by mutect2, varscan2
- MAP3K19 | c.429G>C p.L143F | Missense Mutation (SNP) | VAF 166/516 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAPKBP1 | c.2559A>T p.R853S (on ENST00000456763 / NM_001128608.2; = p.R847S on NM_014994.3) | Missense Mutation (SNP) | VAF 205/380 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MBLAC1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 175/573 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- METRNL | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- MUC12 | c.3713C>G p.P1238R (on ENST00000379442; = p.P1095R on NM_001164462.1) | Missense Mutation (SNP) | VAF 86/1742 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- MUC5B | c.10810G>C p.A3604P | Missense Mutation (SNP) | VAF 44/994 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- NELFB | c.844T>G p.Y282D | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- NLRC3 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 62/568 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NPAP1 | c.1582T>C p.S528P | Missense Mutation (SNP) | VAF 178/697 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, varscan2
- NR3C1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 28/449 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRK | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODC1 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 28/491 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- OLIG1 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 297/612 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); called by muse, varscan2
- OR2A2 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 58/550 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PDGFD | c.479A>T p.K160I | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKIA | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 105/372 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCE1 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 270/423 reads (64%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPL | c.1331T>A p.I444N | Missense Mutation (SNP) | VAF 184/450 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R12C | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 31/1056 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); called by muse, mutect2
- PRRC2A | c.5213C>G p.S1738* | Nonsense Mutation (SNP) | VAF 196/818 reads (24%) | called by muse, mutect2, varscan2
- PSG4 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PSME4 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 69/271 reads (25%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.6800C>T p.A2267V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- R3HDML | c.183A>T p.R61S | Missense Mutation (SNP) | VAF 230/875 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ROBO2 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RP1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 33/710 reads (5%) | called by muse, mutect2
- RPS20 | c.360A>T p.*120Yext*12 | Nonstop Mutation (SNP) | VAF 13/181 reads (7%) | called by muse, mutect2
- RTL3 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SMYD1 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 18/465 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- SPHKAP | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- STRAP | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 97/423 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); called by mutect2, varscan2
- SYNPR | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R42 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 18/609 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2
- TNRC18 | c.7366del p.E2456Rfs*44 | Frame Shift Del (DEL) | VAF 230/611 reads (38%) | called by mutect2, pindel, varscan2
- TNS3 | c.3257A>T p.Q1086L | Missense Mutation (SNP) | VAF 57/824 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- TRABD2B | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 67/618 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP7 | c.2602T>C p.F868L | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- ZNF510 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.519); called by mutect2, varscan2
- ZP4 | c.1414T>C p.S472P | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.1144T>C p.L382= | Silent (SNP) | VAF 28/414 reads (7%) | catalogued as rs1465476093; called by muse, mutect2
- ADAM12 | c.306C>T p.D102= | Silent (SNP) | VAF 23/440 reads (5%) | catalogued as rs370718727; called by muse, mutect2
- ATP2B4 | c.1989C>A p.T663= | Silent (SNP) | VAF 36/432 reads (8%) | called by muse, mutect2
- BCAM | c.1299C>T p.V433= | Silent (SNP) | VAF 25/664 reads (4%) | called by muse, mutect2
- BRSK1 | c.2031G>A p.P677= | Silent (SNP) | VAF 226/459 reads (49%) | catalogued as rs755135302; called by muse, mutect2, varscan2
- CATSPER1 | c.1404C>A p.T468= | Silent (SNP) | VAF 143/460 reads (31%) | called by muse, mutect2, varscan2
- CCDC158 | c.423G>A p.E141= | Silent (SNP) | VAF 19/269 reads (7%) | catalogued as rs745891494, COSV66355488; called by muse, mutect2
- CHFR | c.237C>T p.T79= | Silent (SNP) | VAF 99/323 reads (31%) | called by muse, mutect2, varscan2
- CHPF2 | c.1260C>T p.P420= | Silent (SNP) | VAF 121/775 reads (16%) | called by muse, mutect2, varscan2
- COLEC11 | c.357C>G p.R119= | Silent (SNP) | VAF 48/548 reads (9%) | called by muse, mutect2
- CPLX2 | c.126G>A p.R42= | Silent (SNP) | VAF 185/619 reads (30%) | catalogued as rs773899228; called by muse, mutect2, varscan2
- CRACD | c.2400C>G p.V800= | Silent (SNP) | VAF 36/480 reads (8%) | catalogued as rs781498249; called by muse, mutect2
- EVI5L | c.276G>C p.R92= | Silent (SNP) | VAF 53/682 reads (8%) | catalogued as COSV54488029; called by muse, mutect2
- GABRB2 | c.1023A>G p.A341= | Silent (SNP) | VAF 144/409 reads (35%) | catalogued as rs1208154923, COSV99196692; called by muse, mutect2, varscan2
- GLIPR1L2 | c.84C>G p.L28= | Silent (SNP) | VAF 30/566 reads (5%) | called by muse, mutect2
- GOT1L1 | c.792G>C p.V264= | Silent (SNP) | VAF 136/492 reads (28%) | catalogued as rs750635428; called by muse, mutect2, varscan2
- HEPHL1 | c.1404C>T p.T468= | Silent (SNP) | VAF 30/574 reads (5%) | called by muse, mutect2
- HNRNPC | c.342G>A p.P114= | Silent (SNP) | VAF 113/244 reads (46%) | catalogued as rs751744618, COSV100193467; called by muse, mutect2, varscan2
- HNRNPCL1 | c.843G>A p.E281= | Silent (SNP) | VAF 26/382 reads (7%) | catalogued as rs1164255935; called by muse, mutect2
- HOXB8 | c.210G>A p.Q70= | Silent (SNP) | VAF 66/1015 reads (7%) | catalogued as COSV99493945; called by muse, mutect2
- IFT172 | c.3708T>C p.Y1236= | Silent (SNP) | VAF 134/413 reads (32%) | called by muse, mutect2, varscan2
- IL21R | c.996G>A p.T332= | Silent (SNP) | VAF 74/558 reads (13%) | catalogued as rs1244192788, COSV61970567, COSV61970979; called by muse, mutect2, varscan2
- KIFC2 | c.408G>A p.G136= | Silent (SNP) | VAF 34/1338 reads (3%) | catalogued as COSV56760942, COSV56761108; called by muse, mutect2
- MYBPC3 | c.1152C>T p.T384= | Silent (SNP) | VAF 204/566 reads (36%) | catalogued as rs775237084, COSV57022398, COSV57023784; called by muse, mutect2, varscan2
- NDUFV1 | c.480G>A p.G160= | Silent (SNP) | VAF 33/536 reads (6%) | catalogued as rs1294562179; called by muse, mutect2
- NGF | c.22C>T p.L8= | Silent (SNP) | VAF 14/292 reads (5%) | catalogued as COSV65687782; called by muse, mutect2
- NRDE2 | c.114C>T p.S38= | Silent (SNP) | VAF 152/317 reads (48%) | catalogued as COSV62964820, COSV62964904; called by muse, mutect2, varscan2
- OR5H15 | c.639T>A p.T213= | Silent (SNP) | VAF 19/316 reads (6%) | catalogued as rs530952227; called by muse, mutect2
- PDCD7 | c.882C>G p.L294= | Silent (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.813C>T p.T271= (on ENST00000389212; = p.T229= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/280 reads (46%) | catalogued as rs1002833104, COSV99406021; called by muse, mutect2, varscan2
- RHPN1 | c.747C>T p.A249= | Silent (SNP) | VAF 131/483 reads (27%) | catalogued as rs941760356; called by muse, mutect2, varscan2
- RPS16 | c.318G>A p.K106= | Silent (SNP) | VAF 26/450 reads (6%) | called by muse, mutect2
- RSPH9 | c.738C>G p.G246= | Silent (SNP) | VAF 180/685 reads (26%) | catalogued as COSV64521962; called by muse, mutect2, varscan2
- SCAP | c.507C>T p.C169= | Silent (SNP) | VAF 134/351 reads (38%) | called by muse, mutect2, varscan2
- SPOPL | c.894A>T p.S298= | Silent (SNP) | VAF 30/530 reads (6%) | called by muse, mutect2
- TSTD1 | c.216T>C p.D72= | Silent (SNP) | VAF 208/524 reads (40%) | catalogued as rs1014937973; called by muse, mutect2, varscan2
- ZC3H6 | c.2853A>T p.G951= | Silent (SNP) | VAF 14/319 reads (4%) | called by muse, mutect2
- C5orf38 | c.*90T>A | 3'UTR (SNP) | VAF 41/1514 reads (3%) | called by muse, mutect2
- DBI | c.10-257T>A | Intron (SNP) | VAF 147/356 reads (41%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2273G>A | Intron (SNP) | VAF 46/662 reads (7%) | catalogued as rs777646554, COSV55166149; called by muse, mutect2
- RGR | c.370+1383A>G | Intron (SNP) | VAF 28/416 reads (7%) | called by muse, mutect2
- RGS3 | c.3081-490C>T | Intron (SNP) | VAF 32/335 reads (10%) | called by muse, mutect2
- SLC6A1 | c.1192-10C>T | Intron (SNP) | VAF 52/464 reads (11%) | called by muse, mutect2, varscan2
